Somatic mutation profile of tumor specimen C3L-07985-01 (aliquot CPT0481340006) from CPTAC case C3L-07985, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 69.1 years (25,239 days).
Specimen C3L-07985-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0334079-d51e-488d-ac3b-40252565ac9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07985-31 (Blood Derived Normal), aliquot CPT0481490003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52dc9c71-5379-4e82-b8f1-e4caadf35f95

The open-access MAF lists 231 somatic variants for this specimen: 175 protein-altering or splice-affecting, 43 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 43, Nonsense Mutation 11, Intron 10, Frame Shift Del 3, In Frame Del 2, 3'UTR 1, 5'UTR 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 80/330 reads (24%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.3104G>A p.R1035H | Missense Mutation (SNP) | VAF 106/493 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs201973047; called by muse, mutect2, varscan2
- ABCA5 | c.3287A>G p.Y1096C | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.915); catalogued as rs146196512; called by muse, mutect2, varscan2
- ADGRG3 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 82/325 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.217); catalogued as rs777986530; called by muse, mutect2, varscan2
- AKAP3 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57418712; called by muse, mutect2, varscan2
- ANO10 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 116/465 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs571306863, COSV52734681; called by muse, mutect2, varscan2
- BNC1 | c.2911C>T p.R971C | Missense Mutation (SNP) | VAF 179/545 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766072426, COSV61757106, COSV61758012; called by muse, mutect2, varscan2
- BNC1 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1251464403; called by muse, varscan2
- BPIFA2 | c.463G>C p.A155P | Missense Mutation (SNP) | VAF 40/748 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); catalogued as rs372285288; called by muse, mutect2
- CASS4 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 186/649 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1236494477, COSV64385645; called by muse, mutect2, varscan2
- CASS4 | c.1790C>G p.T597S | Missense Mutation (SNP) | VAF 66/510 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.192); catalogued as COSV64386970; called by muse, mutect2, varscan2
- CBFA2T2 | c.1486G>A p.V496I | Missense Mutation (SNP) | VAF 56/451 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs777795048, COSV60798653; called by muse, mutect2, varscan2
- CCDC54 | c.868A>C p.T290P | Missense Mutation (SNP) | VAF 90/368 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53758044; called by muse, mutect2
- CCL7 | c.110G>C p.R37T | Missense Mutation (SNP) | VAF 48/466 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV52336750, COSV99059616; called by muse, mutect2
- CDH23 | c.3865G>A p.A1289T | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56465669; called by muse, varscan2
- CFAP54 | c.7328T>G p.L2443R | Missense Mutation (SNP) | VAF 62/329 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61575244; called by muse, mutect2, varscan2
- CFHR4 | c.1367A>C p.K456T (on ENST00000367416 / NM_001201551.2; = p.K210T on NM_006684.5) | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.082); catalogued as COSV52226389; called by muse, mutect2, varscan2
- CHGB | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 113/499 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as rs369985726; called by muse, mutect2, varscan2
- CLDN23 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 47/360 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs555145406; called by muse, mutect2, varscan2
- CTNNAL1 | c.1927G>C p.A643P | Missense Mutation (SNP) | VAF 58/242 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.399); catalogued as rs375950356; called by muse, mutect2, varscan2
- CYP2E1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 100/485 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs533468318, COSV53315477; called by muse, mutect2, varscan2
- DGKI | c.3127T>G p.L1043V | Missense Mutation (SNP) | VAF 33/398 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55955713; called by muse, mutect2
- DNAH5 | c.9932C>T p.T3311M | Missense Mutation (SNP) | VAF 138/431 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs1411648234; called by muse, mutect2, varscan2
- DNAH5 | c.387C>G p.F129L | Missense Mutation (SNP) | VAF 124/373 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV54213848; called by muse, mutect2, varscan2
- FAM13C | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs769470326, COSV53257881; called by muse, mutect2, varscan2
- FGA | c.1443A>C p.E481D | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57397372; called by muse, mutect2, varscan2
- FLG2 | c.2933A>T p.E978V | Missense Mutation (SNP) | VAF 112/514 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as COSV66172729; called by muse, mutect2, varscan2
- FSIP2 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1426712184, COSV58093784; called by muse, mutect2, varscan2
- FSTL5 | c.416A>C p.K139T | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV60183600, COSV60210915; called by muse, mutect2, varscan2
- GCK | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 56/430 reads (13%) | catalogued as CD097031, COSV60787707; called by mutect2, varscan2
- GPX8 | c.528A>C p.Q176H | Missense Mutation (SNP) | VAF 46/448 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV57057719; called by muse, mutect2
- GRIPAP1 | c.2482G>A p.V828M | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs782501117; called by muse, mutect2, varscan2
- GRM5 | c.2663C>A p.S888* | Nonsense Mutation (SNP) | VAF 75/346 reads (22%) | catalogued as rs77572262; called by muse, mutect2, varscan2
- GSDMA | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 80/346 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs772260746; called by muse, mutect2, varscan2
- IFIT1B | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.359); catalogued as rs764591858; called by muse, mutect2, varscan2
- IGSF9 | c.1231C>T p.R411C (on ENST00000368094 / NM_001135050.2; = p.R395C on NM_020789.4) | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs1345735278; called by muse, mutect2, varscan2
- INAVA | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 32/444 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs914861033; called by muse, mutect2
- IQCM | c.544T>G p.L182V | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as COSV72432250; called by muse, mutect2, varscan2
- KBTBD11 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.036); catalogued as rs1032893555; called by muse, mutect2, varscan2
- KMT2A | c.6223C>T p.R2075C | Missense Mutation (SNP) | VAF 108/449 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs782301554, COSV100627995, COSV63283015; called by muse, mutect2, varscan2
- KYNU | c.757C>G p.H253D | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933379; called by muse, mutect2, varscan2
- LINGO4 | c.1266G>A p.W422* | Nonsense Mutation (SNP) | VAF 74/775 reads (10%) | catalogued as rs1192558033; called by muse, mutect2
- LRP1B | c.10756A>T p.S3586C | Missense Mutation (SNP) | VAF 43/258 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV67242427; called by muse, mutect2, varscan2
- LRRN1 | c.1779A>C p.E593D | Missense Mutation (SNP) | VAF 72/373 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.724); catalogued as COSV60013344; called by muse, mutect2, varscan2
- MAB21L1 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 68/474 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776765864, COSV59788776, COSV59792977; called by muse, mutect2, varscan2
- MEIS2 | c.13T>G p.Y5D | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV54939315; called by muse, mutect2, varscan2
- MICAL1 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 114/482 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs764182210, COSV62191917; called by muse, mutect2, varscan2
- MUC6 | c.6387_6389del p.S2130del | In Frame Del (DEL) | VAF 116/384 reads (30%) | catalogued as rs765184193; called by pindel, varscan2
- MYCBP2 | c.7321C>T p.L2441F (on ENST00000357337; = p.L2479F on NM_015057.5) | Missense Mutation (SNP) | VAF 141/429 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs771548933; called by muse, mutect2, varscan2
- MYO1H | c.2050T>C p.Y684H | Missense Mutation (SNP) | VAF 59/334 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777645287; called by muse, mutect2, varscan2
- NAV3 | c.5582A>C p.K1861T (on ENST00000397909 / NM_001024383.2; = p.K1839T on NM_014903.6) | Missense Mutation (SNP) | VAF 82/408 reads (20%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.997); catalogued as COSV99896569; called by muse, mutect2, varscan2
- NEB | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 97/436 reads (22%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.673); catalogued as rs757248006; called by muse, mutect2, varscan2
- NES | c.109A>G p.S37G | Missense Mutation (SNP) | VAF 66/460 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs757478670; called by muse, varscan2
- NPRL3 | c.1048G>A p.E350K (on ENST00000611875 / NM_001077350.3; = p.E325K on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs761443880, COSV101302049; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN1 | c.3653C>T p.T1218M | Missense Mutation (SNP) | VAF 98/454 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs201720955, COSV99046034; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10J1 | c.774C>A p.Y258* | Nonsense Mutation (SNP) | VAF 67/394 reads (17%) | catalogued as COSV71129272; called by muse, mutect2, varscan2
- ORM1 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 86/348 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); catalogued as rs762690966; called by muse, mutect2, varscan2
- PCDH9 | c.768A>C p.Q256H | Missense Mutation (SNP) | VAF 83/505 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.526); catalogued as COSV60536573, COSV60537647; called by muse, mutect2, varscan2
- PHTF1 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs200403755; called by muse, mutect2, varscan2
- PLXNA1 | c.4676G>A p.R1559H | Missense Mutation (SNP) | VAF 63/294 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs752837846; called by muse, mutect2, varscan2
- PREX2 | c.3797T>G p.V1266G | Missense Mutation (SNP) | VAF 60/452 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV55755979; called by muse, mutect2, varscan2
- PRKAR1B | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 115/556 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs754010354; called by muse, mutect2, varscan2
- RABEPK | c.994_997del p.V332* | Frame Shift Del (DEL) | VAF 85/641 reads (13%) | catalogued as rs1199302077; called by mutect2, pindel, varscan2
- RASA3 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 178/478 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as rs151017747; called by muse, mutect2, varscan2
- RICTOR | c.3313C>G p.P1105A | Missense Mutation (SNP) | VAF 77/316 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV57129421; called by muse, mutect2, varscan2
- RNPEPL1 | c.1815G>A p.W605* | Nonsense Mutation (SNP) | VAF 65/334 reads (19%) | catalogued as rs376304677; called by muse, mutect2, varscan2
- RXFP2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 46/350 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as rs765460875, COSV100034137; called by muse, mutect2, varscan2
- SCN9A | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 76/366 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as rs199933920; ClinVar: uncertain significance; called by muse, varscan2
- SENP2 | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.284); catalogued as COSV56198984; called by muse, mutect2, varscan2
- SNCAIP | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 104/413 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1344259735; called by muse, mutect2, varscan2
- SPTA1 | c.5946A>C p.Q1982H | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV100934076, COSV63748587, COSV63750147; called by muse, varscan2
- STARD9 | c.3197G>C p.S1066T | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.373); catalogued as rs746297793; called by muse, mutect2, varscan2
- SULT4A1 | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 10/308 reads (3%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.982); catalogued as COSV50782809; called by muse, mutect2
- TAF2 | c.1469C>G p.S490* | Nonsense Mutation (SNP) | VAF 43/469 reads (9%) | catalogued as rs1323346294; called by muse, mutect2
- TCHH | c.4487G>A p.R1496H | Missense Mutation (SNP) | VAF 126/503 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as COSV64273788; called by muse, mutect2, varscan2
- TP53 | c.848_849dup p.T284Afs*62 | Frame Shift Ins (INS) | VAF 72/430 reads (17%) | catalogued as CI126192; called by mutect2, pindel, varscan2
- TRIM13 | c.1178T>C p.V393A | Missense Mutation (SNP) | VAF 54/268 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1024962663; called by muse, mutect2, varscan2
- TRIM64B | c.1280T>A p.L427H | Missense Mutation (SNP) | VAF 68/671 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61693694; called by muse, mutect2
- UCKL1 | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 57/824 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as rs896195670; called by muse, mutect2
- VARS1 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 92/589 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs766191219; called by muse, varscan2
- WDR17 | c.1127T>G p.L376R | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs778121595; called by muse, mutect2, varscan2
- WNT6 | c.976G>A p.G326S | Missense Mutation (SNP) | VAF 61/644 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); catalogued as rs1262183703; called by muse, mutect2
- ZHX3 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 88/515 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58385762; called by muse, mutect2, varscan2
- ZMAT1 | c.154del p.L52Ffs*12 | Frame Shift Del (DEL) | VAF 30/118 reads (25%) | catalogued as COSV100858701, COSV100858956; called by mutect2, pindel, varscan2
- ZNF335 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 84/786 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100533113; called by muse, mutect2, varscan2
- ZNF579 | c.1676G>A p.G559D | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1480253235; called by muse, mutect2
- ZNF667 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 101/272 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV52635018; called by muse, mutect2, varscan2
- A2M | c.1700A>C p.K567T | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- AKT3 | c.1013A>T p.E338V | Missense Mutation (SNP) | VAF 54/574 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANAPC1 | c.4879A>C p.N1627H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.146); called by mutect2, varscan2
- ASTN2 | c.1592G>A p.G531E (on ENST00000313400 / NM_001365069.1; = p.G480E on NM_014010.5) | Missense Mutation (SNP) | VAF 46/297 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP10A | c.2935C>A p.L979M | Missense Mutation (SNP) | VAF 87/369 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP5MPL | c.57A>C p.K19N | Missense Mutation (SNP) | VAF 110/450 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ATXN1 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 41/298 reads (14%) | called by muse, mutect2, varscan2
- BBS10 | c.1856A>C p.K619T | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2
- BCL2L1 | c.74G>A p.S25N | Missense Mutation (SNP) | VAF 68/457 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BICRAL | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 115/560 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC18 | c.3002A>G p.D1001G (on ENST00000343253 / NM_001306076.1; = p.D1002G on NM_206886.4) | Missense Mutation (SNP) | VAF 27/252 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CDC42BPG | c.4289C>T p.P1430L | Missense Mutation (SNP) | VAF 79/295 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CENATAC | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP54 | c.4236A>T p.R1412S | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- CLASP1 | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, varscan2
- CLDN17 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 101/395 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CMKLR1 | c.31T>C p.S11P (on ENST00000312143 / NM_001142344.2; = p.S9P on NM_004072.3) | Missense Mutation (SNP) | VAF 71/284 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- COL8A1 | c.1076A>G p.K359R | Missense Mutation (SNP) | VAF 92/432 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- CPXM2 | c.1777A>G p.S593G | Missense Mutation (SNP) | VAF 79/217 reads (36%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- CSMD3 | c.9976T>G p.S3326A (on ENST00000297405 / NM_001363185.1; = p.S3157A on NM_052900.3) | Missense Mutation (SNP) | VAF 76/415 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- DAGLB | c.1759T>C p.Y587H | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DDIAS | c.2473A>C p.K825Q | Missense Mutation (SNP) | VAF 83/352 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DIP2A | c.3050C>T p.A1017V | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- DISP1 | c.2721C>G p.S907R | Missense Mutation (SNP) | VAF 58/396 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DMXL2 | c.4991T>G p.L1664* | Nonsense Mutation (SNP) | VAF 51/187 reads (27%) | called by muse, mutect2, varscan2
- DOP1A | c.4135T>G p.S1379A | Missense Mutation (SNP) | VAF 79/333 reads (24%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- FANCA | c.3361T>A p.S1121T | Missense Mutation (SNP) | VAF 95/328 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- FAT2 | c.6592C>T p.P2198S | Missense Mutation (SNP) | VAF 49/332 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCRLA | c.405C>G p.F135L (on ENST00000367959; = p.F112L on NM_032738.4) | Missense Mutation (SNP) | VAF 119/482 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FHAD1 | c.3051C>G p.D1017E | Missense Mutation (SNP) | VAF 115/388 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FLT4 | c.740A>C p.K247T | Missense Mutation (SNP) | VAF 81/376 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GLIPR1 | c.523T>C p.Y175H | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIN2D | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GSDMA | c.1243G>T p.G415C | Missense Mutation (SNP) | VAF 45/429 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- H3C13 | c.318A>T p.E106D | Missense Mutation (SNP) | VAF 113/506 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- HNRNPH1 | c.746A>G p.Y249C | Missense Mutation (SNP) | VAF 58/284 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IRAG2 | c.2774A>G p.K925R | Missense Mutation (SNP) | VAF 61/344 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- IRAK2 | c.1648G>C p.G550R | Missense Mutation (SNP) | VAF 119/453 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- JAG1 | c.1390T>C p.C464R | Missense Mutation (SNP) | VAF 55/314 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KBTBD7 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 38/532 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.188); called by muse, mutect2
- KCNK15 | c.893G>T p.R298M | Missense Mutation (SNP) | VAF 118/1518 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by muse, mutect2
- KDR | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- KPNA3 | c.1154A>G p.Q385R | Missense Mutation (SNP) | VAF 78/392 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- KRTAP13-1 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 89/387 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- LANCL1 | c.425A>C p.K142T | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- LCN8 | c.395A>G p.Y132C (on ENST00000612714 / NM_001345934.1; = p.Y109C on NM_178469.3) | Missense Mutation (SNP) | VAF 32/1356 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LRP12 | c.2296G>A p.G766R | Missense Mutation (SNP) | VAF 73/460 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCM9 | c.2902G>T p.V968L | Missense Mutation (SNP) | VAF 88/407 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MRAP | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- MYO1D | c.2186G>T p.R729M | Missense Mutation (SNP) | VAF 71/341 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- NKTR | c.2354A>G p.Y785C | Missense Mutation (SNP) | VAF 82/375 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- OAS2 | c.1828A>C p.K610Q | Missense Mutation (SNP) | VAF 65/288 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- OBSCN | c.19173C>G p.Y6391* | Nonsense Mutation (SNP) | VAF 24/227 reads (11%) | called by muse, varscan2
- OR2S2 | c.13A>C p.N5H | Missense Mutation (SNP) | VAF 66/289 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PABPC5 | c.259A>C p.K87Q | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PAM | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH10 | c.1846C>A p.L616I | Missense Mutation (SNP) | VAF 127/442 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCDH10 | c.2609A>T p.N870I | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- PCDH18 | c.1581C>G p.I527M | Missense Mutation (SNP) | VAF 40/300 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PCDHB9 | c.1583A>G p.D528G | Missense Mutation (SNP) | VAF 118/565 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PHIP | c.2303T>A p.I768K | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, varscan2
- PRDM14 | c.1651T>C p.C551R | Missense Mutation (SNP) | VAF 24/507 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PSAPL1 | c.878C>A p.T293N | Missense Mutation (SNP) | VAF 157/397 reads (40%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RAD23B | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 102/501 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RAG2 | c.868A>T p.I290F | Missense Mutation (SNP) | VAF 106/339 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- RAPH1 | c.2251C>G p.Q751E | Missense Mutation (SNP) | VAF 98/390 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RYR1 | c.13262_13269del p.D4421Gfs*159 | Frame Shift Del (DEL) | VAF 119/447 reads (27%) | called by mutect2, pindel, varscan2
- SERPINF2 | c.1466G>T p.S489I | Missense Mutation (SNP) | VAF 90/372 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC12A5 | c.1602G>C p.Q534H (on ENST00000454036 / NM_001134771.2; = p.Q511H on NM_020708.5) | Missense Mutation (SNP) | VAF 75/876 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SLC17A7 | c.1018G>T p.V340L | Missense Mutation (SNP) | VAF 91/240 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SLC26A2 | c.1796T>C p.L599S | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC44A5 | c.625A>T p.R209* | Nonsense Mutation (SNP) | VAF 27/206 reads (13%) | called by muse, mutect2, varscan2
- SOAT2 | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPIDR | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 72/445 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPPL2A | c.1550T>G p.I517S | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX13C | c.194G>C p.R65T | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- TMPO | c.25T>A p.S9T | Missense Mutation (SNP) | VAF 79/424 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- TNC | c.5192G>T p.R1731M | Missense Mutation (SNP) | VAF 25/418 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2
- TRMT12 | c.1019A>C p.E340A | Missense Mutation (SNP) | VAF 84/469 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRPA1 | c.2075A>C p.N692T | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TRUB2 | c.779A>G p.D260G | Missense Mutation (SNP) | VAF 94/435 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- USP48 | c.2567T>C p.L856P | Missense Mutation (SNP) | VAF 48/722 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); called by muse, mutect2
- VIRMA | c.743_745del p.G248del | In Frame Del (DEL) | VAF 66/411 reads (16%) | called by mutect2, pindel, varscan2
- XIRP2 | c.7456C>A p.Q2486K (on ENST00000628543; = p.Q2661K on NM_152381.6) | Missense Mutation (SNP) | VAF 77/327 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF425 | c.1054C>A p.H352N | Missense Mutation (SNP) | VAF 120/450 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF461 | c.1356G>C p.Q452H | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZNF521 | c.1258G>T p.V420F | Missense Mutation (SNP) | VAF 90/345 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ZNF697 | c.1049T>C p.L350P | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2
- ADAMTS16 | c.2445T>C p.T815= | Silent (SNP) | VAF 109/338 reads (32%) | catalogued as COSV56976480, COSV56976826; called by muse, mutect2, varscan2
- BCKDHB | c.1086T>C p.G362= | Silent (SNP) | VAF 37/376 reads (10%) | called by muse, mutect2
- CARD10 | c.771G>A p.P257= | Silent (SNP) | VAF 56/392 reads (14%) | catalogued as rs992044188; called by muse, mutect2, varscan2
- CLEC9A | c.312A>G p.L104= | Silent (SNP) | VAF 43/202 reads (21%) | called by muse, mutect2, varscan2
- CNOT1 | c.2229A>T p.A743= | Silent (SNP) | VAF 84/489 reads (17%) | called by muse, mutect2, varscan2
- COL12A1 | c.8946G>A p.L2982= | Silent (SNP) | VAF 64/331 reads (19%) | catalogued as COSV59396386; called by muse, mutect2, varscan2
- COL16A1 | c.4341C>T p.I1447= | Silent (SNP) | VAF 99/453 reads (22%) | catalogued as rs1410824473, COSV54702015, COSV54705671; called by muse, mutect2, varscan2
- DPPA5 | c.276C>T p.R92= | Silent (SNP) | VAF 44/216 reads (20%) | called by muse, mutect2, varscan2
- FAM47A | c.180C>T p.Y60= | Silent (SNP) | VAF 52/287 reads (18%) | catalogued as rs774049524, COSV60495082; called by muse, mutect2, varscan2
- FLG2 | c.769A>C p.R257= | Silent (SNP) | VAF 107/460 reads (23%) | catalogued as COSV101166367; called by muse, mutect2, varscan2
- FOXI1 | c.867G>A p.V289= | Silent (SNP) | VAF 116/474 reads (24%) | catalogued as rs77249980, COSV100089335; called by muse, mutect2, varscan2
- GLYR1 | c.1089G>A p.V363= | Silent (SNP) | VAF 79/422 reads (19%) | catalogued as COSV100424477; called by muse, mutect2, varscan2
- GRIN2C | c.3243C>A p.S1081= | Silent (SNP) | VAF 120/468 reads (26%) | called by mutect2, varscan2
- GTF2A1 | c.312G>A p.Q104= | Silent (SNP) | VAF 98/268 reads (37%) | called by muse, mutect2, varscan2
- KCNA1 | c.231G>A p.R77= | Silent (SNP) | VAF 106/353 reads (30%) | catalogued as COSV66836398, COSV66838585; called by muse, mutect2, varscan2
- KCNJ15 | c.267G>A p.A89= | Silent (SNP) | VAF 48/447 reads (11%) | catalogued as rs545197879; called by muse, mutect2, varscan2
- KRT17 | c.648C>T p.A216= | Silent (SNP) | VAF 43/236 reads (18%) | called by muse, mutect2, varscan2
- KRT81 | c.1374C>T p.N458= | Silent (SNP) | VAF 96/445 reads (22%) | catalogued as rs750725979; called by muse, mutect2, varscan2
- LHFPL6 | c.147G>A p.R49= | Silent (SNP) | VAF 98/540 reads (18%) | catalogued as rs1249836271; called by muse, mutect2, varscan2
- LLGL1 | c.2421C>T p.Y807= | Silent (SNP) | VAF 113/589 reads (19%) | catalogued as rs150836582; called by muse, mutect2, varscan2
- LMOD1 | c.324C>G p.A108= | Silent (SNP) | VAF 61/408 reads (15%) | called by muse, mutect2, varscan2
- MPP4 | c.564G>A p.A188= | Silent (SNP) | VAF 59/253 reads (23%) | catalogued as rs759565134, COSV59633965; called by muse, mutect2, varscan2
- MYO16 | c.4122G>A p.A1374= | Silent (SNP) | VAF 177/458 reads (39%) | catalogued as COSV62752985; called by muse, mutect2, varscan2
- NEBL | c.2406C>T p.D802= | Silent (SNP) | VAF 107/662 reads (16%) | catalogued as rs748203517, COSV65802713; ClinVar: likely benign; called by muse, mutect2, varscan2
- OIT3 | c.30C>G p.L10= | Silent (SNP) | VAF 79/290 reads (27%) | called by muse, mutect2, varscan2
- OPN1LW | c.309C>T p.T103= | Silent (SNP) | VAF 86/349 reads (25%) | catalogued as rs782058799, COSV64064242; called by muse, mutect2, varscan2
- POTEF | c.2913C>A p.S971= | Silent (SNP) | VAF 30/464 reads (6%) | called by muse, varscan2
- POTEI | c.2913C>A p.S971= | Silent (SNP) | VAF 54/343 reads (16%) | called by muse, mutect2, varscan2
- PRR14L | c.5364C>G p.T1788= | Silent (SNP) | VAF 50/336 reads (15%) | called by muse, mutect2, varscan2
- PRTG | c.553C>T p.L185= | Silent (SNP) | VAF 30/194 reads (15%) | catalogued as rs753129340; called by muse, mutect2, varscan2
- PTGS2 | c.345T>C p.T115= | Silent (SNP) | VAF 80/335 reads (24%) | catalogued as COSV100821829; called by muse, mutect2, varscan2
- RABGAP1L | c.1737T>C p.T579= | Silent (SNP) | VAF 39/263 reads (15%) | called by muse, mutect2, varscan2
- RHOBTB1 | c.999G>A p.R333= | Silent (SNP) | VAF 96/332 reads (29%) | catalogued as rs1434410105; called by muse, mutect2, varscan2
- SLC12A5 | c.2649T>C p.T883= (on ENST00000454036 / NM_001134771.2; = p.T860= on NM_020708.5) | Silent (SNP) | VAF 53/668 reads (8%) | catalogued as rs1568867810; called by muse, mutect2
- SLC14A2 | c.939G>A p.S313= | Silent (SNP) | VAF 64/325 reads (20%) | catalogued as rs377498712; called by muse, mutect2, varscan2
- SMARCA4 | c.2427C>T p.I809= | Silent (SNP) | VAF 64/212 reads (30%) | catalogued as rs773895427, COSV60789323; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRAPPC9 | c.3000A>G p.E1000= | Silent (SNP) | VAF 103/551 reads (19%) | called by muse, mutect2, varscan2
- TULP2 | c.993T>C p.S331= | Silent (SNP) | VAF 69/415 reads (17%) | called by muse, varscan2
- UGGT1 | c.4329G>A p.Q1443= | Silent (SNP) | VAF 56/254 reads (22%) | called by muse, mutect2, varscan2
- ZBTB43 | c.831G>A p.Q277= | Silent (SNP) | VAF 47/416 reads (11%) | catalogued as rs780738916, COSV100991467; called by muse, mutect2, varscan2
- ZFAND6 | c.246T>G p.S82= | Silent (SNP) | VAF 53/275 reads (19%) | called by muse, mutect2, varscan2
- ZNF606 | c.39T>A p.L13= | Silent (SNP) | VAF 43/334 reads (13%) | called by muse, mutect2, varscan2
- ZNF74 | c.1143C>T p.I381= | Silent (SNP) | VAF 66/964 reads (7%) | catalogued as rs753518856; called by muse, mutect2
- AFF2 | c.1041+56446T>C | Intron (SNP) | VAF 45/162 reads (28%) | called by muse, mutect2, varscan2
- AJAP1 | c.*358C>T | 3'UTR (SNP) | VAF 47/431 reads (11%) | called by muse, mutect2, varscan2
- ATXN8OS | n.499+948A>C | Intron (SNP) | VAF 68/432 reads (16%) | called by muse, mutect2, varscan2
- CCDC57 | c.2564-11586G>C | Intron (SNP) | VAF 74/399 reads (19%) | called by muse, mutect2, varscan2
- CLASP2 | c.716-389G>C | Intron (SNP) | VAF 94/386 reads (24%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-34725A>T | Intron (SNP) | VAF 43/146 reads (29%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-21366T>G | Intron (SNP) | VAF 58/208 reads (28%) | called by muse, varscan2
- MPG | c.-166A>G | 5'UTR (SNP) | VAF 67/336 reads (20%) | called by muse, mutect2, varscan2
- NACA | c.70+3084A>G | Intron (SNP) | VAF 127/484 reads (26%) | catalogued as rs1455102079; called by muse, mutect2, varscan2
- SLC12A5 | chr20:46058662 A>G | 3'Flank (SNP) | VAF 111/1158 reads (10%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-48025A>G | Intron (SNP) | VAF 54/233 reads (23%) | catalogued as rs1161634489; called by muse, mutect2, varscan2
- TRPM3 | c.1154+7631del | Intron (DEL) | VAF 34/163 reads (21%) | called by mutect2, varscan2
- TTN | c.34264+2708A>C | Intron (SNP) | VAF 54/211 reads (26%) | called by muse, mutect2, varscan2
